Gene-level copy-number profile of tumor specimen TCGA-XU-A936-01A from TCGA case TCGA-XU-A936, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 65.5 years (23,924 days).
Specimen TCGA-XU-A936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.27ae23d9-786f-4fbe-94f4-0984040a588a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XU-A936-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d0271235-3e25-4caf-b2de-7fa20d36a5e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,137; copy number 2: 3,061; copy number 3: 29,666; copy number 4: 19,470; copy number 5: 3,882; copy number 6: 876; copy number 7: 1,728.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XU-A936-01A-11D-A427-01): tumor purity 0.39, ploidy 3.48, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,728 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–208,270,667, 1,728 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,137. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
